Somatic mutation profile of tumor specimen 0DU9MU from CCDI case PBCKPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,429 days).
Specimen 0DU9MU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c7c7b79-9799-4fad-80b8-22f04bea143f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9NB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/345bc81a-4b21-4b76-a502-2d56b012a270

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDGFRA | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 1002/1603 reads (63%) | catalogued as COSV57275352; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 1009/1614 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- SLC26A1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 180/863 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs866039640; called by muse, mutect2, varscan2
- BIRC3 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 313/1597 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PHF8 | c.1873C>T p.R625* (on ENST00000357988 / NM_001184896.1; = p.R589* on NM_015107.3) | Nonsense Mutation (SNP) | VAF 569/1987 reads (29%) | called by muse, mutect2, varscan2
